Somatic mutation profile of tumor specimen TCGA-CC-A7II-01A (aliquot TCGA-CC-A7II-01A-11D-A33K-10) from TCGA case TCGA-CC-A7II, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 55.0 years (20,079 days).
Specimen TCGA-CC-A7II-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc44519f-2dba-4dfc-9fa3-adc83914c237.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A7II-10A (Blood Derived Normal), aliquot TCGA-CC-A7II-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83d6e86c-9648-4303-9b1a-fb6ef73b4b3d

The open-access MAF lists 184 somatic variants for this specimen: 140 protein-altering or splice-affecting, 38 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 38, Nonsense Mutation 6, Frame Shift Del 4, Intron 4, In Frame Del 3, Splice Region 2, Splice Site 2, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AC006059.2 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as rs1422345997, COSV59607011; called by muse, mutect2, varscan2
- ACVR2A | c.1373T>C p.I458T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs1490498075, COSV54021809; called by muse, mutect2, varscan2
- ADAMTS18 | c.2164-1G>A p.X722_splice | Splice Site (SNP) | VAF 33/106 reads (31%) | catalogued as COSV51412134; called by muse, mutect2, varscan2
- ADAMTS18 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs891093965, COSV51399337; called by muse, mutect2, varscan2
- ADD2 | c.116C>A p.A39E | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV52455583, COSV52461586; called by muse, mutect2, varscan2
- AHNAK2 | c.7789G>T p.G2597C | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); catalogued as COSV60916091; called by muse, mutect2, varscan2
- AKR1B15 | c.947C>A p.T316N | Missense Mutation (SNP) | VAF 68/119 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.792); catalogued as rs1017204425, COSV71151967; called by muse, mutect2, varscan2
- AMPH | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as COSV57742755; called by muse, mutect2, varscan2
- ANKDD1A | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs553148491, COSV60353072; called by muse, mutect2, varscan2
- ANKRD27 | c.2467C>T p.H823Y | Missense Mutation (SNP) | VAF 279/433 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV60131841; called by muse, mutect2, varscan2
- AP5Z1 | c.1157A>T p.E386V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV62241920; called by muse, mutect2, varscan2
- ARHGAP17 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as rs769354198, COSV51507570; called by muse, mutect2, varscan2
- ARHGAP35 | c.2906A>T p.N969I | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as COSV68331511; called by muse, mutect2, varscan2
- ATP1A3 | c.227C>A p.A76D (on ENST00000545399 / NM_001256214.2; = p.A63D on NM_152296.5) | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV57487839; called by muse, mutect2, varscan2
- BSN | c.11683G>A p.V3895M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.054); catalogued as rs761547616, COSV56518776; called by muse, mutect2, varscan2
- CACNA1S | c.3895C>A p.Q1299K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs1195586602, COSV62939799; called by muse, mutect2, varscan2
- CACNA2D1 | c.2900C>A p.A967D (on ENST00000356253 / NM_001366867.1; = p.A955D on NM_000722.4) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV62380119; called by muse, mutect2, varscan2
- CASP8AP2 | c.4664G>A p.G1555D | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV52747181; called by muse, mutect2, varscan2
- CBLL2 | c.113G>T p.W38L | Missense Mutation (SNP) | VAF 72/90 reads (80%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV60369106; called by muse, mutect2, varscan2
- CCDC141 | c.3947G>T p.S1316I | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.381); catalogued as COSV55374024, COSV55380785; called by muse, mutect2, varscan2
- CCDC71 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58910219; called by muse, mutect2, varscan2
- CDH20 | c.1679C>A p.S560Y | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as COSV53010275; called by muse, mutect2, varscan2
- CELA3B | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61404112; called by muse, mutect2, varscan2
- CHST3 | c.826C>A p.R276S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64151080, COSV64151376; called by muse, mutect2, varscan2
- CLASRP | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 13/337 reads (4%) | SIFT tolerated (0.08); catalogued as COSV99673428; called by muse, mutect2
- CNTNAP3 | c.2888G>T p.S963I | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs1294052650, COSV99903955; called by muse, mutect2, varscan2
- CNTNAP4 | c.3790A>G p.I1264V | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as rs1013424268, COSV56681858; called by muse, mutect2, varscan2
- COL3A1 | c.380G>C p.G127A | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58582021, COSV58584742; called by muse, mutect2, varscan2
- CPT1C | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV54919422; called by muse, mutect2, varscan2
- CRELD2 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58207170; called by muse, mutect2
- DCN | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs993484273, COSV50007195; called by muse, mutect2, varscan2
- DGKI | c.3036G>T p.Q1012H | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as COSV55944358; called by muse, mutect2, varscan2
- DLK2 | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV55088189; called by muse, mutect2, varscan2
- DMD | c.395A>T p.Q132L | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55873052; called by muse, mutect2, varscan2
- DNAH2 | c.10556T>C p.L3519P | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66719929; called by muse, mutect2, varscan2
- DOCK10 | c.4104C>A p.F1368L | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV51403531; called by muse, mutect2, varscan2
- DTX3 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs748571053, COSV54086776; called by muse, mutect2, varscan2
- DUOX1 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772812512, COSV58477078, COSV58481199; called by muse, mutect2, varscan2
- DUS1L | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57649105; called by muse, mutect2, varscan2
- ESPNL | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754801829, COSV54541376; called by muse, mutect2, varscan2
- ESR1 | c.129C>A p.Y43* | Nonsense Mutation (SNP) | VAF 23/56 reads (41%) | catalogued as COSV52791403; called by muse, mutect2, varscan2
- EVA1C | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs766239764, COSV55824302; called by muse, mutect2, varscan2
- EVPL | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56911397; called by muse, mutect2
- EVX2 | c.1415C>A p.A472D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV57963566; called by muse, mutect2
- EZR | c.53T>A p.F18Y | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61453925; called by muse, mutect2, varscan2
- FAM83E | c.1191G>T p.W397C | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV52375426, COSV99572016; called by muse, mutect2, varscan2
- FAM83E | c.1190G>T p.W397L | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99572017; called by muse, mutect2, varscan2
- FER1L6 | c.3304G>T p.V1102L | Missense Mutation (SNP) | VAF 203/255 reads (80%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV67550115; called by muse, mutect2, varscan2
- FGR | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.84); PolyPhen benign (0.072); catalogued as COSV64969523; called by muse, mutect2, varscan2
- FLG | c.7302C>A p.S2434R | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs749473643, COSV64242277; called by muse, mutect2
- FRMPD2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV59715670; called by muse, mutect2, varscan2
- GABRA5 | c.370C>A p.L124I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV59479875, COSV59479912; called by muse, mutect2, varscan2
- GIMAP8 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56231663; called by muse, mutect2, varscan2
- GK2 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV62626947; called by muse, mutect2, varscan2
- GSG1L | c.754C>T p.R252C (on ENST00000447459 / NM_001109763.2; = p.R97C on NM_144675.2) | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs759434857, COSV66578797; called by muse, mutect2, varscan2
- HDLBP | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV60496054; called by muse, mutect2, varscan2
- HIF3A | c.1202C>A p.A401D (on ENST00000377670 / NM_152795.4; = p.A332D on NM_022462.4) | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV52198873; called by muse, mutect2, varscan2
- IGF2BP3 | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV51685162; called by muse, mutect2, varscan2
- ISLR | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV51433919; called by muse, mutect2, varscan2
- ITGAD | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.056); catalogued as COSV66758189; called by muse, mutect2, varscan2
- ITIH5 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV56904999; called by muse, mutect2, varscan2
- KCNK9 | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 214/280 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV57280013, COSV57282008; called by muse, mutect2
- KIAA1958 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs759469555, COSV61723938; called by muse, mutect2, varscan2
- KMT2B | c.5621G>T p.R1874L | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV55861459; called by muse, mutect2, varscan2
- KRT4 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as COSV53407486; called by muse, mutect2, varscan2
- KRT76 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60120435; called by muse, mutect2, varscan2
- LOXL1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs566197761, COSV56093456; called by muse, mutect2, varscan2
- LRATD1 | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as COSV54472863; called by muse, mutect2, varscan2
- MALSU1 | c.19G>T p.V7L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV54978598; called by muse, mutect2, varscan2
- MAP3K1 | c.2221A>G p.I741V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.891); catalogued as COSV68123915; called by muse, mutect2, varscan2
- MAP3K4 | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV62333892; called by muse, mutect2, varscan2
- MAP4K1 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV50264113; called by muse, mutect2, varscan2
- MARCHF6 | c.1294G>T p.V432F | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56881721; called by muse, mutect2, varscan2
- MPEG1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57090977; called by muse, mutect2
- MRPS2 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54093083; called by muse, mutect2, varscan2
- MYH3 | c.5273A>G p.K1758R | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV56865238; called by muse, mutect2, varscan2
- MYO18B | c.4847C>A p.A1616D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59135164; called by muse, mutect2, varscan2
- NCDN | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57845910; called by muse, mutect2, varscan2
- NCOA6 | c.4772C>T p.P1591L | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV62860947; called by muse, mutect2, varscan2
- NEURL1 | c.1680C>A p.C560* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV63509854; called by muse, mutect2, varscan2
- NIBAN3 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56309577; called by muse, mutect2, varscan2
- NLRP5 | c.1633G>T p.V545L | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs775936118, COSV66764715; called by muse, mutect2, varscan2
- NOS3 | c.994G>C p.A332P | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52490136, COSV99871256; called by muse, mutect2, varscan2
- NPHP3 | c.458A>C p.Q153P | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as CM161066, COSV58129588; called by muse, mutect2, varscan2
- NPTX2 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55717322; called by muse, mutect2, varscan2
- NXF3 | c.1158C>T p.A386= | Splice Region (SNP) | VAF 56/74 reads (76%) | catalogued as COSV67703618; called by muse, mutect2, varscan2
- OBSCN | c.16795G>A p.G5599S | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52777343; called by muse, mutect2, varscan2
- OBSCN | c.22135G>T p.A7379S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62411762; called by muse, mutect2, varscan2
- OR4D5 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58307110; called by muse, mutect2, varscan2
- OR51G1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58969367; called by muse, mutect2, varscan2
- OTOF | c.2699G>T p.G900V (on ENST00000272371 / NM_194248.3; = p.G153V on NM_004802.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55503572; called by muse, mutect2, varscan2
- PACSIN3 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.375); catalogued as COSV54066210; called by muse, mutect2, varscan2
- PCDHA8 | c.1786G>T p.A596S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs1554139748, COSV65326873; called by muse, mutect2, varscan2
- PDE8A | c.2438G>T p.W813L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59637180; called by muse, mutect2, varscan2
- PDZRN4 | c.1721C>A p.A574D (on ENST00000402685 / NM_001164595.2; = p.A316D on NM_013377.4) | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV54202509; called by muse, mutect2, varscan2
- PHF21B | c.1416G>T p.Q472H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as COSV57558515; called by muse, mutect2, varscan2
- POLR3D | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 46/963 reads (5%) | catalogued as COSV60571308; called by muse, mutect2
- PRAMEF17 | c.454G>T p.D152Y | Missense Mutation (SNP) | VAF 117/254 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV65816321, COSV65816525; called by muse, mutect2, varscan2
- PTGER4 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV56720962; called by muse, mutect2, varscan2
- RNF123 | c.2459G>T p.R820L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100570855, COSV59687436; called by muse, mutect2, varscan2
- RNF17 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.02); catalogued as rs140457030; called by muse, mutect2, varscan2
- RYR2 | c.12425C>T p.A4142V | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs765312361, COSV63687093; called by muse, mutect2, varscan2
- SCG2 | c.1366C>A p.P456T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV59540203, COSV59541141; called by muse, mutect2, varscan2
- SCN10A | c.4570G>T p.V1524F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV71861489; called by muse, mutect2, varscan2
- SLC16A12 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV57950326, COSV57953759; called by muse, mutect2, varscan2
- SLC6A3 | c.1266C>A p.S422R | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54364542, COSV54366912; called by muse, mutect2, varscan2
- SMARCA2 | c.2992-1G>T p.X998_splice | Splice Site (SNP) | VAF 32/76 reads (42%) | catalogued as COSV61809078; called by muse, mutect2, varscan2
- SMARCA2 | c.2992G>C p.G998R | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100570158; called by muse, mutect2, varscan2
- SMC4 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 112/288 reads (39%) | catalogued as COSV100644144, COSV61004964; called by muse, mutect2, varscan2
- SORCS1 | c.2161T>C p.C721R | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53868394; called by muse, mutect2, varscan2
- SORT1 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56666550; called by muse, mutect2, varscan2
- SSH1 | c.1328A>G p.Y443C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346792156, COSV58456646; called by muse, mutect2, varscan2
- SSTR5 | c.692C>A p.A231E | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as COSV53512285; called by muse, mutect2, varscan2
- TASOR2 | c.7036T>C p.F2346L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV60167594; called by muse, mutect2, varscan2
- TBX4 | c.1290C>A p.S430R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV53607248, COSV53608194; called by muse, mutect2, varscan2
- TCF20 | c.3223C>G p.P1075A | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV59491596; called by muse, mutect2, varscan2
- TECTA | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs370652301; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TET1 | c.2641A>G p.M881V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs764721765, COSV65384961; called by muse, mutect2, varscan2
- TLR5 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60559232; called by muse, mutect2, varscan2
- TPK1 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63641237; called by muse, mutect2, varscan2
- TPM1 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV51261556; called by muse, mutect2, varscan2
- TRPM2 | c.2258T>A p.L753Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV55970099; called by muse, mutect2, varscan2
- UQCRH | c.246G>T p.V82= | Splice Region (SNP) | VAF 113/217 reads (52%) | catalogued as COSV61176497; called by muse, mutect2, varscan2
- VCP | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs932872788, COSV62720658; called by muse, mutect2, varscan2
- WDR17 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.219); catalogued as COSV54574627; called by muse, mutect2, varscan2
- ZFP91 | c.1117A>G p.I373V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV60159023; called by muse, mutect2, varscan2
- ZNF28 | c.2116C>G p.L706V | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV60423294; called by muse, mutect2, varscan2
- ZNF677 | c.1129T>C p.C377R | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61720331; called by muse, mutect2
- ZNF71 | c.1180C>A p.R394S | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.043); catalogued as COSV60146278, COSV60147995; called by muse, mutect2, varscan2
- ZNF74 | c.89C>G p.S30W | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1435006666, COSV62621116, COSV62623724; called by muse, mutect2, varscan2
- ZNF831 | c.2480T>C p.V827A | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV64040585; called by muse, mutect2, varscan2
- ADPRHL1 | c.121_148del p.G41Qfs*6 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- CRACDL | c.1131_1148delinsGCA p.A378_P383delinsQ | In Frame Del (DEL) | VAF 9/43 reads (21%) | called by pindel, varscan2*
- ITGAV | c.147_158del p.F49_V53delinsL | In Frame Del (DEL) | VAF 62/187 reads (33%) | called by mutect2, pindel, varscan2
- LRRK2 | c.5070dup p.I1691Yfs*6 | Frame Shift Ins (INS) | VAF 30/79 reads (38%) | called by mutect2, pindel, varscan2
- MYO1F | c.292_306del p.L98_E102del | In Frame Del (DEL) | VAF 21/51 reads (41%) | called by mutect2, pindel, varscan2
- POLDIP3 | c.1062del p.I355Sfs*11 | Frame Shift Del (DEL) | VAF 35/121 reads (29%) | called by mutect2, pindel, varscan2
- TATDN3 | c.37_53del p.C13Gfs*3 | Frame Shift Del (DEL) | VAF 44/149 reads (30%) | called by mutect2, pindel, varscan2
- ZNF829 | c.412del p.I138Ffs*13 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- ABCC12 | c.3816C>A p.L1272= | Silent (SNP) | VAF 41/136 reads (30%) | catalogued as COSV60914160, COSV60914171; called by muse, mutect2, varscan2
- ACOXL | c.369T>C p.C123= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV61325245; called by muse, mutect2, varscan2
- AGBL1 | c.2841G>A p.K947= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs1338039141, COSV66859053; called by muse, mutect2, varscan2
- ALG1 | c.33G>A p.L11= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV52157740, COSV52158843; called by muse, mutect2, varscan2
- ANKFN1 | c.2127G>A p.Q709= | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV59447951; called by muse, varscan2
- ARID3B | c.504C>T p.V168= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV60557790; called by muse, mutect2, varscan2
- C2orf16 | c.4683C>A p.P1561= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV62675842; called by muse, mutect2, varscan2
- CCDC81 | c.741A>G p.K247= (on ENST00000445632 / NM_001156474.2; = p.K157= on NM_021827.4) | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV53578639; called by muse, mutect2, varscan2
- CCDC97 | c.151C>T p.L51= | Silent (SNP) | VAF 67/96 reads (70%) | catalogued as COSV54190038, COSV54190419; called by muse, mutect2, varscan2
- CELSR2 | c.6252G>T p.L2084= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV54772362; called by muse, mutect2, varscan2
- COL23A1 | c.1542C>A p.G514= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV66790948, COSV66794765; called by muse, mutect2, varscan2
- DLGAP2 | c.1404G>T p.L468= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV70098684; called by muse, mutect2
- DSCAM | c.447C>T p.S149= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV68639283; called by muse, mutect2, varscan2
- EGFLAM | c.2382C>T p.A794= | Silent (SNP) | VAF 99/168 reads (59%) | catalogued as COSV59303299, COSV59321767; called by muse, mutect2, varscan2
- EP400 | c.282G>T p.L94= | Silent (SNP) | VAF 114/223 reads (51%) | catalogued as COSV57772901; called by muse, mutect2, varscan2
- ESR2 | c.658C>A p.R220= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV50830407, COSV50831495; called by muse, mutect2, varscan2
- FSHB | c.285A>T p.P95= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV54221819; called by muse, mutect2, varscan2
- GDF5 | c.204G>C p.G68= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV65501713, COSV65503895; called by muse, mutect2, varscan2
- GEMIN5 | c.2334A>G p.S778= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as COSV53560834; called by muse, mutect2, varscan2
- GNMT | c.174C>T p.C58= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV55103248; called by muse, mutect2, varscan2
- IGSF22 | c.373C>T p.L125= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV60034476; called by muse, mutect2
- KIAA2026 | c.2971T>C p.L991= | Silent (SNP) | VAF 59/160 reads (37%) | catalogued as rs746159415, COSV67355095; called by muse, mutect2, varscan2
- KLHL6 | c.1419C>A p.I473= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV58066553, COSV58068929; called by muse, mutect2, varscan2
- MAPRE3 | c.582C>T p.G194= | Silent (SNP) | VAF 45/110 reads (41%) | catalogued as rs113977877, COSV51867199; called by muse, mutect2, varscan2
- OBSCN | c.13062C>A p.G4354= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV52777322; called by muse, mutect2, varscan2
- PCNX3 | c.3534G>A p.A1178= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs768105990, COSV63136943, COSV63139658; called by muse, mutect2, varscan2
- PLCD3 | c.747G>T p.R249= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV59560598; called by muse, mutect2, varscan2
- PLEKHG4B | c.738C>A p.I246= (on ENST00000283426; = p.I602= on NM_052909.5) | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV52047962, COSV52049774; called by muse, mutect2, varscan2
- PRKD1 | c.1461C>T p.A487= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as COSV59570002; called by muse, mutect2, varscan2
- PTGDS | c.228C>A p.G76= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV56400474; called by muse, mutect2, varscan2
- SCRIB | c.1608C>T p.P536= | Silent (SNP) | VAF 91/116 reads (78%) | catalogued as rs546935238, COSV57587342; called by muse, mutect2, varscan2
- SHISAL1 | c.570G>T p.P190= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV66988006, COSV66988682; called by muse, mutect2, varscan2
- STAB2 | c.2883C>A p.T961= | Silent (SNP) | VAF 52/164 reads (32%) | catalogued as COSV101185667, COSV66335582, COSV66345583; called by muse, mutect2, varscan2
- SYT1 | c.510C>T p.P170= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs369758844; called by muse, mutect2, varscan2
- TBX21 | c.561G>A p.V187= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV51596279; called by muse, mutect2, varscan2
- XRCC4 | c.255G>C p.T85= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV56538439, COSV56547794; called by muse, mutect2, varscan2
- ZBTB25 | c.369G>T p.V123= | Silent (SNP) | VAF 76/163 reads (47%) | catalogued as COSV67198573; called by muse, mutect2, varscan2
- ZNF585B | c.1764C>T p.I588= | Silent (SNP) | VAF 101/485 reads (21%) | catalogued as COSV100459260; called by muse, varscan2
- CDC37 | c.-21G>T | 5'UTR (SNP) | VAF 5/35 reads (14%) | catalogued as rs766721158, COSV99705638; called by muse, mutect2, varscan2
- CTBP2 | c.58+12563C>T | Intron (SNP) | VAF 40/92 reads (43%) | catalogued as rs1200109239, COSV58341783; called by muse, mutect2, varscan2
- NEBL | c.164+46405G>A | Intron (SNP) | VAF 31/90 reads (34%) | catalogued as COSV65798577; called by muse, mutect2, varscan2
- SERPINA3 | c.-48G>A | 5'UTR (SNP) | VAF 21/62 reads (34%) | catalogued as COSV101261600; called by muse, mutect2, varscan2
- TTN | c.34523-147C>A | Intron (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100591341; called by muse, mutect2, varscan2
- WDR33 | c.725-11255T>G | Intron (SNP) | VAF 34/64 reads (53%) | catalogued as COSV100460616, COSV59249215; called by muse, varscan2
